Somatic mutation profile of cancer-model specimen HCM-BROD-0231-C25-85N (3D Organoid, passage 4; aliquot HCM-BROD-0231-C25-85N-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0231-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.9 years (25,156 days).
Specimen HCM-BROD-0231-C25-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c233271-2fc3-469b-8d41-7c7a5a05728d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0231-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0231-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74d760dc-3569-4172-b54c-1da1ee32abf3

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Splice Region 2, In Frame Del 2, Frame Shift Del 1, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 104/104 reads (100%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ARHGEF33 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 30/580 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1168165122; called by muse, mutect2
- ARID1A | c.3391C>G p.Q1131E | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61376561, COSV61380004; called by mutect2, varscan2
- CARD11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 269/521 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1298741148, COSV67802261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNRIP1 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs781162109, COSV55150814; called by muse, mutect2
- MAN2A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs1359989748; called by muse, mutect2, varscan2
- MYO18A | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 18/501 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100572734; called by muse, mutect2
- NRXN1 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453687; called by muse, mutect2, varscan2
- POLR1G | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs549329477, COSV100338161, COSV100338395; called by muse, mutect2, varscan2
- POTEJ | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs764378487; called by muse, mutect2, varscan2
- SEC61A1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 176/375 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs767658338, COSV54578190; called by muse, mutect2, varscan2
- SHMT2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 257/507 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760592358, COSV61073422; called by muse, mutect2, varscan2
- SLC6A9 | c.1653C>T p.Y551= (on ENST00000360584 / NM_201649.4; = p.Y497= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 132/265 reads (50%) | catalogued as rs200915117, COSV62212040; called by muse, mutect2, varscan2
- SLFN14 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 164/308 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1274661246; called by muse, mutect2, varscan2
- TBC1D10B | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 205/424 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374035939, COSV59768069; called by muse, mutect2, varscan2
- USH2A | c.9526C>A p.P3176T | Missense Mutation (SNP) | VAF 153/271 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.261); catalogued as COSV56356532; called by muse, mutect2, varscan2
- ZNF479 | c.1460A>T p.H487L | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs1304699593; called by muse, mutect2
- AANAT | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACAP3 | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 33/760 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARID1A | c.3398_3401del p.P1133Lfs*27 | Frame Shift Del (DEL) | VAF 154/162 reads (95%) | called by pindel, varscan2
- ATP1A4 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 160/322 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 73/237 reads (31%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 272/606 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- C12orf42 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 259/554 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL4A2 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2
- DHX40 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DOP1B | c.3961A>T p.S1321C | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ENOX2 | c.917A>T p.E306V (on ENST00000338144 / NM_001382520.1; = p.E277V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/526 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- EPB41L3 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 67/659 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPS8L2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 190/382 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LONRF3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 105/485 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRFIP2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MAGI2 | c.2969A>G p.D990G | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6B3 | c.199T>G p.S67A | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLXNA3 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- PMPCA | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 215/442 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POU2AF1 | c.456G>T p.T152= | Splice Region (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- PPP1R36 | c.424_426del p.T142del | In Frame Del (DEL) | VAF 85/89 reads (96%) | called by pindel, varscan2
- SLCO3A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 140/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYCP2 | c.2322G>T p.L774F | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); called by muse, mutect2
- TRIM3 | c.1391A>T p.K464M | Missense Mutation (SNP) | VAF 56/366 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRIM31 | c.12dup p.Q5Afs*81 | Frame Shift Ins (INS) | VAF 198/284 reads (70%) | called by mutect2, pindel, varscan2
- USF3 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 155/295 reads (53%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR12 | c.360T>A p.D120E | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.4022T>G p.V1341G | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BCAR1 | c.1584T>C p.N528= | Silent (SNP) | VAF 275/480 reads (57%) | called by muse, mutect2, varscan2
- CR2 | c.2172G>T p.V724= | Silent (SNP) | VAF 112/235 reads (48%) | called by muse, mutect2, varscan2
- LAS1L | c.1932C>T p.D644= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as rs748382959, COSV56706596; called by muse, mutect2, varscan2
- MACF1 | c.13368C>G p.R4456= (on ENST00000372915; = p.R2389= on NM_012090.5) | Silent (SNP) | VAF 330/332 reads (99%) | called by muse, mutect2, varscan2
- PDGFRA | c.2985C>T p.N995= | Silent (SNP) | VAF 175/370 reads (47%) | catalogued as rs138801854; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTCHD3 | c.408G>A p.A136= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as rs766544434, COSV71256670; called by muse, varscan2
- SLC25A45 | c.609G>A p.T203= | Silent (SNP) | VAF 126/264 reads (48%) | catalogued as rs370780233; called by muse, mutect2, varscan2
- SLC8A1 | c.1674G>A p.V558= | Silent (SNP) | VAF 41/341 reads (12%) | catalogued as COSV60478824; called by muse, mutect2, varscan2
- SMARCA1 | c.948A>C p.I316= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- TBC1D25 | c.522C>T p.G174= | Silent (SNP) | VAF 152/190 reads (80%) | called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 292/635 reads (46%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- AGTPBP1 | c.-59C>T | 5'UTR (SNP) | VAF 19/642 reads (3%) | catalogued as rs1275396367; called by muse, mutect2
- GH2 | c.457-33C>A | Intron (SNP) | VAF 95/336 reads (28%) | catalogued as COSV60426287, COSV60426704; called by muse, mutect2, varscan2
- TBC1D29P | n.2788G>A | RNA (SNP) | VAF 204/380 reads (54%) | catalogued as rs761058128, COSV70434072; called by muse, varscan2
